Somatic mutation profile of tumor specimen TARGET-10-PAPZXI-09A (aliquot TARGET-10-PAPZXI-09A-01D) from TARGET case TARGET-10-PAPZXI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,107 days).
Specimen TARGET-10-PAPZXI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d1d5b2e-dc0f-41de-b92a-aff3555728d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZXI-10A (Blood Derived Normal), aliquot TARGET-10-PAPZXI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85bd38db-c063-402d-aeec-6ac88e45cf43

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Splice Region 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs886039463, CM090464, COSV104418166, COSV61005528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.6254G>T p.G2085V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58127322; called by muse, mutect2, varscan2
- ARHGEF16 | c.1305+6T>C | Splice Region (SNP) | VAF 4/42 reads (10%) | catalogued as rs1318596554; called by muse, mutect2
- DCAF4L1 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as rs547538687; called by muse, mutect2
- PRRC1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs141931246; called by muse, mutect2, varscan2
- SEPTIN4 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | catalogued as rs750341271, COSV100050765; called by muse, mutect2, varscan2
- SLC16A5 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as rs756129373, COSV61676979; called by muse, mutect2, varscan2
- C1orf167 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2
- FBXL18 | c.1583G>A p.G528D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); called by muse, mutect2
- LCOR | c.1633_1634insT p.T545Ifs*8 | Frame Shift Ins (INS) | VAF 22/129 reads (17%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.2577C>A p.R859= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV58162691; called by muse, mutect2, varscan2
